Somatic mutation profile of tumor specimen TCGA-28-5213-01A (aliquot TCGA-28-5213-01A-01D-1486-08) from TCGA case TCGA-28-5213, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.5 years (26,491 days).
Specimen TCGA-28-5213-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1cdbdb5d-22f8-429a-93cb-2ededc14fd68.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-28-5213-10A (Blood Derived Normal), aliquot TCGA-28-5213-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48fc7957-a80c-484e-a1af-f6ac751a870a

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 38, Silent 13, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 51/279 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADCY1 | c.1871G>A p.G624D | Missense Mutation (SNP) | VAF 62/374 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV52031807; called by muse, mutect2, varscan2
- AHNAK | c.13652C>T p.P4551L | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV57207164; called by muse, mutect2, varscan2
- ASMT | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 107/514 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.019); catalogued as rs759145050, COSV67109662; called by muse, mutect2, varscan2
- CASR | c.2425C>T p.R809W (on ENST00000490131; = p.R886W on NM_000388.4) | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as CM076072, COSV56135440; called by muse, mutect2, varscan2
- CCDC85A | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.223); catalogued as rs1435565443, COSV68148619, COSV68156051; called by muse, mutect2, varscan2
- CDH15 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV57022642; called by muse, mutect2, varscan2
- DGKE | c.791G>T p.C264F | Missense Mutation (SNP) | VAF 47/241 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV52349189; called by muse, mutect2, varscan2
- ERP44 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs1248924033, COSV52430431; called by muse, mutect2, varscan2
- GHSR | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.148); catalogued as rs1417374938, COSV53837994; called by muse, mutect2, varscan2
- GRIN2A | c.4354C>T p.R1452C | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs568622613, COSV58025217, COSV58049968; called by muse, mutect2, varscan2
- GRIN2A | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1360906241, CM138247, COSV58021739; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGFN1 | c.3173C>T p.T1058M (on ENST00000295591 / NM_001367841.1; = p.T3515M on NM_001164586.2) | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145852390; called by muse, mutect2, varscan2
- KDM2B | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV65638883; called by muse, mutect2, varscan2
- LEXM | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1401825123, COSV64022324; called by muse, mutect2, varscan2
- LRP1 | c.2996A>G p.D999G | Missense Mutation (SNP) | VAF 47/215 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54505055; called by muse, varscan2
- MAPKAPK3 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.011); catalogued as rs375412266, COSV63596787, COSV63597001; called by muse, mutect2, varscan2
- MIDN | c.1274G>A p.G425D | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.888); catalogued as COSV56294479; called by muse, mutect2, varscan2
- MOB3C | c.365T>C p.M122T | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1380308825, COSV54718660; called by muse, mutect2, varscan2
- MPLKIP | c.481A>G p.S161G | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV59320020; called by muse, mutect2, varscan2
- MUC16 | c.17537G>T p.R5846M | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs373641303; called by muse, mutect2, varscan2
- NEXMIF | c.1442G>A p.R481Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50023931; called by muse, mutect2, varscan2
- NTN1 | c.1093G>A p.G365R | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51479105; called by muse, mutect2, varscan2
- OR2T33 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 82/420 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs755082412, COSV58814714; called by muse, mutect2, varscan2
- PFAS | c.279-1G>A p.X93_splice | Splice Site (SNP) | VAF 25/172 reads (15%) | catalogued as COSV58979137; called by muse, mutect2, varscan2
- PNKD | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs777574834, COSV51231307, COSV99282122; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR1B | c.1288T>C p.F430L | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV54495876; called by muse, mutect2, varscan2
- PYHIN1 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.771); catalogued as rs773413126, COSV100932382, COSV63721794; called by muse, mutect2, varscan2
- RESF1 | c.3796A>C p.S1266R | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV57020401; called by muse, mutect2, varscan2
- SACS | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as COSV66536515; called by muse, mutect2, varscan2
- SGO1 | c.184A>G p.K62E | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV55423117; called by muse, mutect2, varscan2
- SLCO6A1 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 122/642 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.139); catalogued as rs144293843, COSV65806739; called by muse, mutect2, varscan2
- SPTA1 | c.5270G>A p.R1757H | Missense Mutation (SNP) | VAF 75/361 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs779823270, COSV63750484; called by muse, mutect2, varscan2
- TAS1R1 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60227277; called by muse, mutect2, varscan2
- TCHH | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 45/205 reads (22%) | PolyPhen possibly damaging (0.635); catalogued as COSV64273667; called by muse, mutect2, varscan2
- TFAP2B | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.245); catalogued as COSV53825873; called by muse, mutect2, varscan2
- TRPM3 | c.2935G>A p.V979M (on ENST00000357533 / NM_001366142.2; = p.V822M on NM_020952.6) | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs760896360, COSV62582102; called by muse, mutect2, varscan2
- UBE3B | c.32G>A p.W11* | Nonsense Mutation (SNP) | VAF 63/281 reads (22%) | catalogued as COSV55092034; called by muse, mutect2, varscan2
- UGT3A2 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as rs375117011; called by muse, mutect2, varscan2
- WDFY3 | c.8041G>A p.G2681R | Missense Mutation (SNP) | VAF 96/475 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV55695917; called by muse, mutect2, varscan2
- ATP10A | c.2551C>T p.L851= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV63514992; called by muse, mutect2, varscan2
- FUT3 | c.651C>T p.L217= | Silent (SNP) | VAF 50/230 reads (22%) | catalogued as rs975639768, COSV54604948; called by muse, mutect2, varscan2
- GANAB | c.1863C>T p.A621= | Silent (SNP) | VAF 37/191 reads (19%) | catalogued as rs192967712, COSV60462894; called by muse, mutect2, varscan2
- KLHDC7A | c.1461G>A p.R487= | Silent (SNP) | VAF 41/162 reads (25%) | catalogued as COSV68769252; called by muse, varscan2
- KMT2A | c.9033A>C p.S3011= | Silent (SNP) | VAF 44/199 reads (22%) | catalogued as COSV63283425; called by muse, mutect2, varscan2
- MATN4 | c.207C>T p.N69= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV59212971; called by muse, mutect2, varscan2
- MUS81 | c.163C>T p.L55= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV57378872; called by muse, mutect2, varscan2
- NR0B1 | c.282G>A p.P94= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV66763741, COSV66764402; called by muse, mutect2, varscan2
- OR2AT4 | c.42C>T p.P14= | Silent (SNP) | VAF 31/135 reads (23%) | catalogued as rs201772462, COSV100532375, COSV59406566; called by muse, mutect2, varscan2
- PATJ | c.900C>T p.N300= | Silent (SNP) | VAF 33/145 reads (23%) | catalogued as rs756597467, COSV57157725; called by muse, mutect2, varscan2
- RSPO1 | c.516C>T p.S172= | Silent (SNP) | VAF 76/249 reads (31%) | catalogued as rs918027632, COSV62973521; called by muse, mutect2, varscan2
- SUN3 | c.246T>C p.Y82= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV52049388; called by muse, mutect2, varscan2
- TTN | c.90273G>A p.P30091= (on ENST00000591111; = p.P22667= on NM_003319.4) | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as rs752309744, COSV59941000; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
